Somatic mutation profile of tumor specimen 0DK5H8 from CCDI case PBBXIX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.2 years (5,566 days).
Specimen 0DK5H8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61dce566-2335-41b6-9f4d-299cfd781d38.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DK5HN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9bb6de5-8b32-4674-892e-a26effa5636c

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDAH2 | c.716G>C p.G239A | Missense Mutation (SNP) | VAF 134/1080 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 10/300 reads (3%) | called by muse, mutect2
